CCG case CUPP-B48X — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/25dea4e1-1810-4bdc-98c1-5ef7a4cffd70

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1966; Vital status: Dead; Days to death: 9 days; Year of death: 2017; Cause of death: Cancer Related.

Diagnoses (1)
1. Neoplasm, malignant, uncertain whether primary or metastatic: ICD-O-3 morphology code: 8000/9; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 51.7 years (18,898 days); Year of diagnosis: 2017; Method of diagnosis: Surgical Resection; AJCC clinical M: M1; AJCC pathologic M: M1; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Lung, NOS / Pleura / Peritoneum, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 9 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 120 kg; Height: 178 cm; BMI: 37.9.
- Timepoint category: Prior to Diagnosis; Comorbidities: Allergies.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1987; Tobacco smoking quit year: 2017.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Cancer; Relationship sex at birth: female.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B48X-NT1-A: Sample type: FFPE Scrolls; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B48X-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample CUPP-B48X-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B48X-TTM1-A-2-0-S1: Section location: Top; Percent tumor cells: 13; Percent tumor nuclei: 38; Percent normal cells: 46; Percent necrosis: 1; Percent stromal cells: 40; Percent lymphocyte infiltration: 45; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
